TCGA case TCGA-BR-8369 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f89ac782-e0b2-4e62-844d-2e00d10a1c65

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Ukraine; Age at index: 76 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.1; Tissue or organ of origin: Fundus of stomach; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 76.8 years (28,051 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N3a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 427 days (1.2 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 7; Lymph nodes tested: 15.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 420 days (1.1 years); Days to treatment end: 427 days (1.2 years); Treatment anatomic sites: Distant Site.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Bone, NOS. Age at diagnosis: 77.9 years (28,470 days); Days to diagnosis: 419 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Days to follow up: 25 days; Disease response: Tumor Free.
- Day 419 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 419 days (1.1 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 427 days (1.2 years); Disease response: With Tumor.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BR-8369-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.3; Intermediate dimension: 2.2; Shortest dimension: 0.4.
  Slide TCGA-BR-8369-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25.
  Slide TCGA-BR-8369-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
- Sample TCGA-BR-8369-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BR-8369-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Antrum/Distal; Lymph nodes examined: Yes; Cancer procurement city: Kiev.
- Follow-up form: Lost to follow-up: Yes; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No; New tumor event site other: Bone; Treatment outcome first course: Complete Remission/Response.
- Follow-up form, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Follow-up form, New neoplasm event types: New tumor event type: Distant Metastasis.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 427 days; disease-specific survival: no event (censored), 427 days; disease-free interval: event (new tumor event after initially disease-free), 419 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 419 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BR-8369-01A-11D-2338-01): tumor purity 0.29, ploidy 3.34, whole-genome doublings 1.
